Surgical pathology report (de-identified scan), TCGA case TCGA-GF-A3OT, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site ABS - IUPUI, specimen TCGA-GF-A3OT-06A (Metastatic).

[page 1 of 3]
ICA-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary 177-3

hw
2/5/12

Specimen Received:

- A: Axillary brachioplexus mass
- B: Brachioplexus sheath
- C: Excision melanoma left arm long proximal 12 o'clock
- D: Right back lesion

Final Pathologic Diagnosis:

- A. Axillary brachioplexus mass, dissection:

Metastatic melanoma in several, matted lymph nodes, the exact number is unclear.

Extranodal extension: Present.

Size: 10.2 cm.

Two of six discernible discrete lymph nodes positive for metastatic melanoma.

Extension to within 1 HPF of the inked surgical edge of the specimen

Findings supported by positive S100, melanA, HMB45, tyrosinase.

- B. Brachioplexus sheath, biopsy:

Metastatic melanoma, myxoid appearing, with extranodal extension, margins involved

- C. Skin, left upper arm, wide re-excisional biopsy:

0.7 cm focus of intradermal malignant melanoma.

Margins widely clear of melanoma.

Adjacent scar, see note

DIF: Nondiagnostic study, see note

- D. Right back lesion: Skin, excision:

Compound nevus with architectural disorder (dysplastic nevus) and mild to moderate cytologic atypia, margins free with adjacent seborrheic keratosis.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:

C: The adjacent scar suggests that this is locally recurrent disease. DIF was also performed. Granular IgM is noted at the basement membrane zone which is a nonspecific finding. If there is continuing concern to establish a diagnosis of lupus in this patient, correlation with serologic studies as well as lesional biopsy should be considered.

Gross Description:

The specimen is received in four parts each labeled with the patient name.

[page 2 of 3]
Part A received fresh for Procurement with acquisition of tissue labeled "axillary brachial plexus mass" and consists of a irregular, lobulated, rubbery mass which has dimensions of 10.2 x 7.4 x 5.6 cm. The external surface is gray-yellow to red-brown, smooth and glistening to shaggy with focal cautery effect. The specimen is received previously incised. The specimen is inked and further sectioned to reveal a pink-tan to red-black, focally granular, focally myxoid, focally hemorrhagic and focally degenerated cut surface. This process extends to the inked external surface at numerous sites. Also, within the fat at the periphery there are seven discrete lymph nodes identified that range from 0.4 to 2.2 cm in greatest dimension. The two larger lymph nodes are grossly positive. Representative sections are submitted as labeled:

- A1-4 mass;
- A5 three lymph nodes submitted in toto;
- A6,7 representative sections of two grossly positive lymph nodes;
- A8 two lymph nodes submitted in toto.

Part B received in formalin labeled "brachial plexus sheath" and consists of an aggregate of irregular, ragged, gray-yellow to red-brown soft tissues which has dimensions of 4.0 x 3.0 x 1.0 cm. The soft tissues are remarkable for myxoid and hemorrhagic foci. Representative sections are submitted in cassette B.

Part C received in formalin labeled "excision melanoma left arm proximal 12 o'clock" and consists of an ellipse of gray-tan, wrinkled skin which has dimensions of 11.6 x 5.2 cm and is excised to a maximal depth of 2.4 cm. The specimen is received with a suture at the proximal/12 o'clock tip. The specimen is inked in the following manner: 12 to 6 o'clock-blue, 6 to 12 o'clock-black and deep-red. The epidermis is remarkable for a central, gray-tan, raised lesion which has dimensions of 1.0 x 0.7 x 0.4 cm. This lesion is 2.0 cm from the nearest 2 o'clock margin. Additionally, there is some mottling surrounding this lesion. Additionally, there is a irregular, ill-defined area of hypopigmented skin adjacent to this lesion (3 o'clock side) which has dimensions of 1.0 x 1.0 cm and is 1.2 cm from the nearest 3 o'clock margin and 0.6 cm from the previously described lesion. The specimen is serially sectioned to reveal a gray-yellow, lobulated, glistening cut surface. The cut surface of the lesion is pink-tan and fleshy with focal granularity. This lesion extends to within 1.9 cm of the nearest deep margin. Representative sections are submitted as labeled:

- C1 12 o'clock tip;
- C2 6 o'clock tip;
- C3-38 central cross-sections to include bisected contiguous sections in cassette C3 and C4, C5 and C6, C7 and C8 and trisected contiguous sections in cassette C9-11, C12-14, C15-17, C18-20, C21-23, C24-26, C27-29, C30-32, C33-35, C36-38. Tissue submitted in cassette C3-38 are submitted sequentially from 12 o'clock to 6 o'clock.

Part D received in formalin labeled "right back lesion" and consists of an ellipse of gray-tan, wrinkled skin which has dimensions of 1.5 x 0.6 cm and is excised to a maximal depth of 0.4 cm. The epidermis is remarkable for a central, gray-brown, mottled and somewhat granular lesion which has dimensions of 0.4 x

[page 3 of 3]
0.4 by just less than 0.2 cm. This lesion extends to within 0.1 cm of the nearest cutaneous margin. The specimen is inked, serially sectioned to reveal a gray-tan, fibrous cut surface. This lesion extends to within 0.6 cm of the nearest deep margin. The specimen is entirely submitted as labeled:

D1 tips;

D2 central cross-sections.

Microscopic Description:

DIF

IgG: Negative

IgA: Negative

IgM: 1+ granular staining along the basement membrane zone

C3: Negative

Fibrinogen: Negative

END OF REPORT

Taken: DOB: (Age: Gender:

Source: NCI Genomic Data Commons file 8d7db686-803b-4934-83ee-8dba1e1674b7 (TCGA-GF-A3OT.B41FFF2A-C253-47D3-9C22-BCCF724F7519.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).